Somatic mutation profile of tumor specimen TCGA-DJ-A3UQ-01A (aliquot TCGA-DJ-A3UQ-01A-11D-A22D-08) from TCGA case TCGA-DJ-A3UQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 45.3 years (16,545 days).
Specimen TCGA-DJ-A3UQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e87fd53-3f73-49a2-87fc-9d94f95c0b2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3UQ-10A (Blood Derived Normal), aliquot TCGA-DJ-A3UQ-10A-01D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98af3745-24b4-4cba-a4de-044081e587db

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CD5 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61718928, COSV61718942; called by muse, mutect2
- CLCN5 | c.1744G>A p.A582T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs1557194571, COSV56586324, COSV56587136; called by muse, mutect2, varscan2
- MAP2K6 | c.254G>C p.R85P | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as COSV63007510, COSV63007908; called by muse, mutect2, varscan2
- NWD1 | c.3695T>C p.I1232T | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs138963732; called by muse, mutect2, varscan2
- POU4F3 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57944667; called by muse, mutect2
- ADSS2 | c.936G>A p.E312= | Silent (SNP) | VAF 4/90 reads (4%) | catalogued as rs1459656619, COSV63695959; called by muse, mutect2
- FPR2 | c.438C>T p.I146= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as rs200320548, COSV100389426, COSV60672026; called by muse, varscan2
